Somatic mutation profile of tumor specimen TARGET-30-PALWIP-01A (aliquot TARGET-30-PALWIP-01A-01W) from TARGET case TARGET-30-PALWIP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 3.4 years (1,232 days).
Specimen TARGET-30-PALWIP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9da812e8-bd48-466b-88eb-1dcf4533a837.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALWIP-10A (Blood Derived Normal), aliquot TARGET-30-PALWIP-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1def10d9-cf78-4e9d-9bdd-060801a40482

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM1 | c.1139G>T p.W380L | Missense Mutation (SNP) | VAF 111/354 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV54634311; called by muse, mutect2, varscan2
- CEP68 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs750523258; called by mutect2, varscan2
- MYOZ3 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV51739084, COSV51739602; called by mutect2, varscan2
- OR4K17 | c.528C>A p.S176R | Missense Mutation (SNP) | VAF 180/533 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59647692; called by muse, mutect2, varscan2
- ZNF274 | c.793G>T p.A265S (on ENST00000610905; = p.A160S on NM_016324.3) | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV58763642; called by muse, mutect2, varscan2
- ZNF480 | c.438G>T p.R146S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); catalogued as COSV57995388; called by muse, mutect2, varscan2
- JADE2 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); called by mutect2, varscan2
- NPY1R | c.232C>T p.L78= | Silent (SNP) | VAF 49/122 reads (40%) | catalogued as COSV56713930; called by muse, mutect2, varscan2
